Somatic mutation profile of tumor specimen TCGA-60-2708-01A (aliquot TCGA-60-2708-01A-01D-1522-08) from TCGA case TCGA-60-2708, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.9 years (23,691 days).
Specimen TCGA-60-2708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a7fb0e-400e-4b9e-8174-80a1d9da9458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2708-11A (Solid Tissue Normal), aliquot TCGA-60-2708-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42240ff8-ac09-4fe4-9c49-1904d27bad8c

The open-access MAF lists 231 somatic variants for this specimen: 170 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 55, Frame Shift Del 12, Nonsense Mutation 12, Splice Region 3, RNA 3, 5'Flank 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7784T>C p.L2595P | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV71289347; called by muse, mutect2, varscan2
- ABCD4 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1204078851, COSV53992851, COSV53995075; called by muse, mutect2
- ADAM21 | c.1186A>T p.N396Y | Missense Mutation (SNP) | VAF 189/266 reads (71%) | SIFT tolerated (0.89); PolyPhen benign (0.05); catalogued as COSV50796291; called by muse, mutect2, varscan2
- ADAM33 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV62935126; called by muse, mutect2, varscan2
- ADAMTS20 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67132970, COSV67140910; called by muse, mutect2, varscan2
- ADGRG4 | c.526C>A p.R176S | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV54951846, COSV54957798; called by muse, mutect2, varscan2
- AFF4 | c.2039C>A p.S680* | Nonsense Mutation (SNP) | VAF 94/165 reads (57%) | catalogued as COSV54795579; called by muse, mutect2, varscan2
- AOX1 | c.2921T>A p.I974N | Missense Mutation (SNP) | VAF 97/201 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV65982056; called by muse, mutect2, varscan2
- APBB1IP | c.1482G>C p.K494N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV66133037; called by muse, mutect2, varscan2
- APPBP2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs140223877; called by muse, mutect2, varscan2
- ARMCX2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV57530317, COSV57531528; called by muse, mutect2, varscan2
- ASNSD1 | c.326del p.L109Cfs*107 | Frame Shift Del (DEL) | VAF 60/376 reads (16%) | catalogued as rs763026988; called by mutect2, pindel, varscan2
- B3GNT7 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365561743, COSV55006671; called by muse, mutect2, varscan2
- BRINP3 | c.1879A>T p.I627F | Missense Mutation (SNP) | VAF 132/572 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.326); catalogued as COSV66526989; called by muse, mutect2, varscan2
- C1R | c.871G>A p.D291N (on ENST00000536053 / NM_001354346.2; = p.D277N on NM_001733.7) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs775244665, COSV73293806; called by muse, mutect2, varscan2
- CACNA1A | c.4922T>G p.V1641G | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64200153; called by muse, mutect2, varscan2
- CACNG2 | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV55635821; called by muse, mutect2, varscan2
- CASS4 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV64386769; called by muse, mutect2, varscan2
- CCNJL | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV57445187; called by muse, mutect2, varscan2
- CDK5 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52523107; called by muse, mutect2, varscan2
- CDX4 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV65171698; called by muse, mutect2, varscan2
- CENPF | c.8218A>T p.S2740C | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV65275581; called by muse, mutect2, varscan2
- CENPT | c.201G>T p.R67S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV54650236; called by muse, mutect2, varscan2
- CHMP3 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55686404, COSV99806491; called by muse, mutect2, varscan2
- CHMP4B | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54136199; called by muse, mutect2
- CNGA3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs770308610, CM101949, COSV55623584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGB3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 236/822 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs146488853, COSV99082035; called by muse, mutect2, varscan2
- CNTN4 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.264); catalogued as COSV61874368; called by muse, mutect2, varscan2
- CRCP | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV58535870; called by muse, mutect2, varscan2
- CRYBG3 | c.8626C>G p.Q2876E | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51712540; called by muse, mutect2, varscan2
- CSMD3 | c.2218G>T p.G740W (on ENST00000297405 / NM_001363185.1; = p.G636W on NM_052900.3) | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52217569; called by muse, mutect2, varscan2
- CSRNP1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 63/122 reads (52%) | catalogued as rs1427983004, COSV56187097, COSV56188330; called by muse, mutect2, varscan2
- CYLC1 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61412724; called by muse, mutect2, varscan2
- DAB1 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 90/142 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100139985, COSV59729336; called by muse, mutect2, varscan2
- DCSTAMP | c.373A>T p.M125L | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs760646948, COSV52578096; called by muse, mutect2, varscan2
- DENND3 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 139/249 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52803026; called by muse, mutect2, varscan2
- DGKZ | c.2549A>G p.Y850C (on ENST00000454345 / NM_001105540.2; = p.Y662C on NM_003646.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV58989656; called by muse, varscan2
- DNAJC14 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 106/338 reads (31%) | catalogued as COSV57913181; called by muse, mutect2, varscan2
- EFL1 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV51606331; called by muse, mutect2, varscan2
- ENPP3 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as COSV62954575; called by muse, mutect2, varscan2
- EPB41L2 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 48/387 reads (12%) | catalogued as COSV61356176; called by muse, mutect2, varscan2
- FAIM2 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739707; called by muse, mutect2, varscan2
- FAM102A | c.494C>T p.P165L (on ENST00000373095 / NM_001035254.3; = p.P23L on NM_203305.2) | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV55947712; called by muse, mutect2, varscan2
- FAM107B | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV51686090; called by muse, mutect2, varscan2
- FAM27E5 | n.276C>T | Splice Region (SNP) | VAF 33/145 reads (23%) | catalogued as rs544493136; called by muse, mutect2
- FAM47A | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV60497417; called by muse, mutect2, varscan2
- FHL5 | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58738007; called by muse, mutect2, varscan2
- FLNA | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61044508; called by muse, mutect2, varscan2
- FLRT2 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 282/384 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs988486068, COSV58143368; called by muse, varscan2
- FNIP1 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 187/355 reads (53%) | catalogued as COSV57197045; called by muse, mutect2, varscan2
- FRMD3 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV58462914; called by muse, mutect2, varscan2
- GOLGA3 | c.4241T>A p.L1414Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52633541; called by muse, mutect2, varscan2
- GRIA4 | c.1370A>G p.H457R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV56900349; called by muse, mutect2, varscan2
- HCK | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1299403458, COSV52943396; called by muse, mutect2, varscan2
- HECW1 | c.1445C>A p.T482N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV67831307; called by muse, mutect2, varscan2
- HECW1 | c.3728T>A p.F1243Y | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67831313; called by muse, mutect2, varscan2
- HNRNPH2 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 102/500 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.059); catalogued as COSV57266273; called by muse, mutect2, varscan2
- HOXC11 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV54533356; called by muse, varscan2
- HRNR | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV100912733, COSV64259033; called by muse, mutect2, varscan2
- HSPA6 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59060757; called by muse, mutect2, varscan2
- HSPA6 | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV59061489; called by muse, mutect2
- HTR2A | c.720T>A p.F240L | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.071); catalogued as COSV66327488; called by muse, mutect2, varscan2
- IGBP1 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60556513; called by muse, mutect2
- IL17REL | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as rs376895359, COSV58008359; called by muse, mutect2, varscan2
- IQSEC2 | c.1043G>A p.R348H (on ENST00000642864 / NM_001111125.3; = p.R143H on NM_015075.2) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64725700; called by muse, mutect2, varscan2
- ITPKB | c.2322C>G p.I774M | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV55263096, COSV99684488, COSV99685002; called by muse, mutect2, varscan2
- JADE3 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54467105; called by muse, mutect2, varscan2
- JADE3 | c.1574C>A p.T525K | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV54467111; called by muse, mutect2, varscan2
- KALRN | c.5346G>T p.K1782N (on ENST00000360013 / NM_001024660.4; = p.K85N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV52258178; called by muse, mutect2
- KIF15 | c.3451C>A p.H1151N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58161457; called by muse, mutect2, varscan2
- KLHL40 | c.1304A>G p.Y435C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55134897; called by muse, mutect2, varscan2
- KRT37 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV56658352; called by muse, mutect2, varscan2
- KRT6A | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 125/369 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105598; called by muse, mutect2, varscan2
- LAMB1 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 76/211 reads (36%) | catalogued as COSV55965878; called by muse, mutect2, varscan2
- LRCH4 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs769644731, COSV53826630; called by muse, mutect2, varscan2
- LRRC42 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as COSV59961031, COSV59961486; called by muse, mutect2, varscan2
- LRRC7 | c.406G>C p.D136H (on ENST00000651989 / NM_001370785.2; = p.D103H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV104377469, COSV50473346; called by muse, mutect2, varscan2
- LRRIQ3 | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV63044831; called by muse, mutect2, varscan2
- MAGEA11 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.267); catalogued as rs141055931, COSV60756127; called by muse, mutect2
- MAGEB6B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs752201353, COSV69689719; called by muse, mutect2, varscan2
- MAN1A2 | c.180_184del p.S61Tfs*5 | Frame Shift Del (DEL) | VAF 68/249 reads (27%) | catalogued as COSV62979181; called by mutect2, pindel, varscan2
- MAPK13 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52983363; called by muse, mutect2
- MED12 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV100375970; called by muse, mutect2, varscan2
- MTPN | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as rs1259441024, COSV67599742; called by muse, mutect2, varscan2
- MYH14 | c.5288A>T p.E1763V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51820480; called by muse, mutect2, varscan2
- MYO18A | c.3090C>T p.D1030= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as rs752966597, COSV62862118; called by muse, mutect2, varscan2
- NEU1 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57667561; called by muse, mutect2, varscan2
- NF1 | c.8466G>C p.Q2822H (on ENST00000358273 / NM_001042492.3; = p.Q2801H on NM_000267.3) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62206245; called by muse, mutect2, varscan2
- NLRP8 | c.967A>C p.T323P | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV52588732, COSV99405333; called by muse, mutect2, varscan2
- NPEPL1 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs780074914, COSV61939342; called by muse, mutect2
- NRK | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54598385; called by muse, mutect2, varscan2
- NUCKS1 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 254/605 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV65652994; called by muse, mutect2, varscan2
- OPHN1 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62782904; called by muse, mutect2, varscan2
- OR10G8 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV70908649; called by muse, mutect2, varscan2
- OR11H12 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 402/584 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV73543668; called by muse, mutect2, varscan2
- OR2F1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67331513; called by muse, mutect2, varscan2
- OR2G3 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); catalogued as COSV60681959; called by muse, mutect2, varscan2
- OR2T1 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 79/495 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV63542126; called by muse, mutect2, varscan2
- OR4D11 | c.584T>A p.L195H | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57585852; called by muse, mutect2
- OR51I1 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374695087, COSV66508167; called by muse, mutect2, varscan2
- OR5M11 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV73141846; called by muse, mutect2, varscan2
- OR8H1 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57294375; called by muse, mutect2, varscan2
- PARN | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV58366977; called by muse, mutect2, varscan2
- PCDH11X | c.3032C>A p.P1011Q | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs758409007, COSV53446504; called by muse, mutect2, varscan2
- PCDH19 | c.2904C>A p.D968E (on ENST00000373034 / NM_001184880.2; = p.D920E on NM_020766.3) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55264658; called by muse, mutect2, varscan2
- PCDHB10 | c.905T>G p.F302C | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1554284075, COSV53379744; called by muse, mutect2, varscan2
- PCDHB3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV50570468; called by muse, mutect2, varscan2
- PCDHGB2 | c.820A>C p.N274H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV53963391; called by muse, mutect2, varscan2
- PEAK1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56930084, COSV56936742; called by muse, mutect2, varscan2
- PEX5L | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as COSV55847502; called by muse, mutect2, varscan2
- PHKA1 | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV59806900; called by muse, mutect2, varscan2
- PIK3C2B | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV65803728; called by muse, mutect2, varscan2
- PLEKHA8 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV51651685; called by muse, mutect2, varscan2
- PLXNA3 | c.1521C>G p.H507Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754390; called by muse, mutect2, varscan2
- PODN | c.1583T>A p.L528Q (on ENST00000395871; = p.L480Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014336; called by muse, varscan2
- PPARGC1B | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 8/9 reads (89%) | catalogued as COSV58529949; called by muse, mutect2, varscan2
- PPP1R26 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 127/238 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1274929918, COSV63355856; called by muse, mutect2, varscan2
- PRPF4B | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61784409; called by muse, mutect2, varscan2
- RFX3 | c.2153C>G p.P718R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV65861313; called by muse, mutect2, varscan2
- RXFP1 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57051118; called by muse, mutect2, varscan2
- RYR2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200685968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL2 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as rs946358719, COSV58103776; called by muse, mutect2, varscan2
- SETX | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 131/225 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56387201; called by muse, mutect2, varscan2
- SHF | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 138/230 reads (60%) | catalogued as COSV52049442, COSV52050825; called by muse, mutect2, varscan2
- SIPA1L1 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62170802; called by muse, mutect2, varscan2
- SKAP1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as COSV61147380, COSV61152106; called by muse, mutect2, varscan2
- SLC17A2 | c.726T>A p.S242R | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV55352572; called by muse, mutect2, varscan2
- SLC35A2 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV55944967; called by muse, mutect2, varscan2
- SMARCA2 | c.2301G>A p.M767I | Missense Mutation (SNP) | VAF 219/351 reads (62%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.954); catalogued as COSV61808573; called by muse, mutect2, varscan2
- SMOC2 | c.1192G>A p.V398M (on ENST00000356284 / NM_001166412.2; = p.V409M on NM_022138.3) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs754482354, COSV62439085; called by muse, mutect2, varscan2
- SPATA2 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV56866869; called by muse, mutect2, varscan2
- SPTBN2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV59453560; called by muse, mutect2, varscan2
- SRRM4 | c.874T>G p.S292A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.146); catalogued as COSV57418035; called by muse, mutect2, varscan2
- STAT1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV63116443, COSV63117578; called by muse, mutect2, varscan2
- STK39 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63598070; called by muse, mutect2, varscan2
- SYNGAP1 | c.1873C>T p.L625F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53382144, COSV99537858; called by muse, mutect2
- SYT10 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 164/530 reads (31%) | catalogued as COSV57341346, COSV99951367; called by muse, mutect2, varscan2
- TAB3 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.306); catalogued as COSV55837638; called by muse, mutect2, varscan2
- TECRL | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1055028800, COSV67087591; called by muse, mutect2, varscan2
- TFDP3 | c.372G>T p.R124S | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV59537160; called by muse, mutect2, varscan2
- THOC3 | c.627C>T p.L209= | Splice Region (SNP) | VAF 96/586 reads (16%) | catalogued as COSV99442176; called by muse, varscan2
- TLE1 | c.1852G>C p.G618R | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 41/88 reads (47%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TRIM42 | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs778325086, COSV53883675; called by muse, mutect2, varscan2
- TRIM58 | c.1218A>C p.E406D | Missense Mutation (SNP) | VAF 107/487 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as COSV63570669; called by muse, mutect2, varscan2
- TROAP | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57744642; called by muse, mutect2, varscan2
- USP29 | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.362); catalogued as COSV54143502; called by muse, mutect2, varscan2
- UTP14A | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64087056; called by muse, mutect2, varscan2
- VCL | c.2321_2324del p.S774Wfs*9 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as COSV53010977; called by mutect2, pindel, varscan2
- VPS41 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs377296574; called by muse, mutect2, varscan2
- VSIG4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775339601, COSV66073482; called by muse, mutect2, varscan2
- WNK1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60036854; called by muse, mutect2
- ZFHX4 | c.1020A>T p.K340N | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.691); catalogued as COSV50682756, COSV50970085, COSV51469134; called by muse, mutect2, varscan2
- ZFP42 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58817768; called by muse, mutect2, varscan2
- ZGLP1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58533224; called by muse, mutect2
- ZNF41 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57443214; called by muse, mutect2, varscan2
- ZXDA | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV62388159; called by muse, mutect2, varscan2
- ATP1A2 | c.327_336del p.F110Tfs*57 | Frame Shift Del (DEL) | VAF 55/377 reads (15%) | called by mutect2, pindel, varscan2
- CNOT4 | c.1772_1774del p.N591del (on ENST00000541284 / NM_001190850.1; = p.N588del on NM_001190849.2) | In Frame Del (DEL) | VAF 95/290 reads (33%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2216A>T p.H739L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EIF2AK1 | c.1230del p.C411Vfs*17 | Frame Shift Del (DEL) | VAF 56/265 reads (21%) | called by mutect2, pindel, varscan2
- GDF10 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRCC1 | c.1214dup p.P406Afs*4 | Frame Shift Ins (INS) | VAF 54/220 reads (25%) | called by pindel, varscan2
- LRRCC1 | c.1215_1216del p.K405Nfs*4 | Frame Shift Del (DEL) | VAF 70/234 reads (30%) | called by muse*, mutect2, varscan2*
- NDUFS1 | c.211_236del p.V71Cfs*2 | Frame Shift Del (DEL) | VAF 41/268 reads (15%) | called by mutect2, pindel
- PICALM | c.569del p.N190Mfs*3 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- RBM15 | c.515_516del p.L172Qfs*10 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | called by mutect2, pindel, varscan2
- TTN | c.102212_102218del p.N34071Mfs*37 (on ENST00000591111; = p.N26647Mfs*37 on NM_003319.4) | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- VN1R5 | c.458T>A p.L153* | Nonsense Mutation (SNP) | VAF 84/345 reads (24%) | called by muse, mutect2, varscan2
- ZNF43 | c.516del p.K172Nfs*18 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, varscan2
- ADAM22 | c.1992A>G p.L664= | Silent (SNP) | VAF 129/398 reads (32%) | catalogued as COSV55969422, COSV55978930; called by muse, mutect2, varscan2
- ADCY1 | c.1485G>T p.P495= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV52035834; called by muse, mutect2, varscan2
- ADCY8 | c.501A>G p.E167= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV53911286; called by muse, mutect2, varscan2
- AJUBA | c.1395C>T p.A465= | Silent (SNP) | VAF 189/240 reads (79%) | catalogued as COSV52985482, COSV99400827; called by muse, mutect2, varscan2
- ARFGEF3 | c.231G>A p.S77= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as rs138636575; called by muse, mutect2, varscan2
- ARHGAP6 | c.414C>T p.D138= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV61629006; called by muse, mutect2, varscan2
- ARID1B | c.4368T>C p.N1456= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs769362465, COSV51665019; called by muse, mutect2, varscan2
- ATP7B | c.2979G>A p.T993= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as rs200656411, COSV54439477; called by muse, mutect2, varscan2
- BCAN | c.834G>A p.Q278= | Silent (SNP) | VAF 51/245 reads (21%) | catalogued as COSV61257287; called by muse, mutect2, varscan2
- CACNA1S | c.3201C>G p.T1067= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV62940425; called by muse, mutect2, varscan2
- CHRNA4 | c.714C>T p.V238= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV64719756; called by muse, mutect2, varscan2
- CLCN4 | c.1089C>A p.T363= | Silent (SNP) | VAF 63/358 reads (18%) | catalogued as COSV66466869; called by muse, mutect2, varscan2
- COX10 | c.336G>A p.K112= | Silent (SNP) | VAF 57/100 reads (57%) | catalogued as COSV55405569; called by muse, mutect2, varscan2
- CTAG2 | c.324C>T p.I108= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs1557241531, COSV55995230, COSV99909220; called by muse, mutect2, varscan2
- CYP2A13 | c.27G>A p.V9= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV57838290; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DUSP11 | c.813C>T p.L271= | Silent (SNP) | VAF 83/319 reads (26%) | catalogued as rs761885998, COSV55593987; called by muse, mutect2, varscan2
- DYNC2LI1 | c.966C>T p.V322= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as rs752987596, COSV53183763; called by muse, mutect2, varscan2
- EIF4G2 | c.579C>T p.L193= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs1258630610, COSV60597412; called by muse, mutect2, varscan2
- EP400 | c.4710A>T p.I1570= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as COSV57774908; called by muse, mutect2, varscan2
- EPG5 | c.1374C>G p.L458= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV56350936; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1821A>G p.P607= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs769929150, COSV51618958; called by muse, mutect2, varscan2
- ETAA1 | c.552A>T p.T184= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV55473376; called by muse, mutect2, varscan2
- EXPH5 | c.459A>C p.A153= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV56203353; called by muse, mutect2, varscan2
- GLA | c.630C>A p.P210= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV54509664; called by muse, mutect2, varscan2
- H2BC7 | c.354C>A p.A118= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs773729867, COSV61912028; called by muse, mutect2, varscan2
- HOXC12 | c.654C>T p.R218= | Silent (SNP) | VAF 108/287 reads (38%) | catalogued as COSV54535119; called by muse, mutect2, varscan2
- IGKV2D-28 | c.351A>T p.L117= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV101494561, COSV101494564; called by mutect2, varscan2
- ITPR2 | c.4908A>G p.E1636= | Silent (SNP) | VAF 97/267 reads (36%) | catalogued as rs1488842987, COSV67270468; called by muse, mutect2, varscan2
- LDOC1 | c.57G>C p.L19= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV65159366; called by muse, mutect2, varscan2
- MAGEA3 | c.387G>A p.P129= | Silent (SNP) | VAF 123/323 reads (38%) | catalogued as rs144510184, COSV64756262; called by muse, mutect2, varscan2
- NCAN | c.3063G>C p.G1021= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as COSV53052369; called by muse, mutect2, varscan2
- NID2 | c.513C>T p.R171= | Silent (SNP) | VAF 30/566 reads (5%) | catalogued as COSV53497522; called by muse, mutect2
- NLGN3 | c.2151C>T p.S717= (on ENST00000358741 / NM_181303.2; = p.S697= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV62443609; called by muse, mutect2, varscan2
- NLRP6 | c.2007A>C p.G669= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV56460146; called by muse, mutect2, varscan2
- OR10S1 | c.748C>A p.R250= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV73342827; called by muse, mutect2, varscan2
- OR51I2 | c.148C>A p.R50= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs145725236, COSV58298994; called by muse, mutect2, varscan2
- OR5W2 | c.231T>A p.T77= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV60616484; called by muse, mutect2, varscan2
- PDE4DIP | c.6006A>G p.K2002= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57699978; called by mutect2, varscan2
- PLCL1 | c.2286G>A p.S762= | Silent (SNP) | VAF 57/232 reads (25%) | catalogued as rs144546582; called by muse, mutect2, varscan2
- PTER | c.327G>T p.T109= | Silent (SNP) | VAF 58/94 reads (62%) | catalogued as rs147446984, COSV54346040; called by muse, mutect2, varscan2
- RBAK | c.1941A>G p.G647= | Silent (SNP) | VAF 18/366 reads (5%) | catalogued as COSV62331619; called by muse, mutect2
- RBBP9 | c.411C>T p.D137= | Silent (SNP) | VAF 95/180 reads (53%) | catalogued as rs565219087, COSV61499970; called by muse, mutect2, varscan2
- REM1 | c.663C>T p.F221= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV52428221; called by muse, mutect2
- SHPRH | c.3480G>A p.Q1160= (on ENST00000275233 / NM_001042683.3; = p.Q1169= on NM_173082.3) | Silent (SNP) | VAF 76/177 reads (43%) | catalogued as rs1247830255, COSV51611385; called by muse, mutect2, varscan2
- SPOPL | c.1155A>T p.P385= | Silent (SNP) | VAF 314/648 reads (48%) | catalogued as COSV54513932; called by muse, mutect2, varscan2
- TMC2 | c.1107C>T p.G369= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs749847002, COSV62653726; called by muse, mutect2, varscan2
- TRADD | c.438G>A p.R146= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV50757894, COSV50758100; called by muse, mutect2, varscan2
- TTBK1 | c.123G>T p.G41= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV52489226, COSV52492209; called by muse, mutect2, varscan2
- TTN | c.97305G>A p.K32435= (on ENST00000591111; = p.K25011= on NM_003319.4) | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as COSV60112712; called by muse, mutect2, varscan2
- VANGL2 | c.687G>A p.V229= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV63604638; called by muse, mutect2, varscan2
- ZC4H2 | c.450C>A p.P150= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs1388052176, COSV62004363; called by muse, mutect2, varscan2
- ZNF292 | c.5757A>G p.L1919= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs768040177, COSV60540560; called by muse, mutect2, varscan2
- ZNF600 | c.1686C>T p.T562= | Silent (SNP) | VAF 80/529 reads (15%) | catalogued as COSV57742998; called by muse, mutect2, varscan2
- ZNF883 | c.87C>A p.T29= | Silent (SNP) | VAF 128/190 reads (67%) | catalogued as COSV71309118; called by muse, mutect2, varscan2
- ANK1 | c.5395-1245G>A | Intron (SNP) | VAF 20/41 reads (49%) | catalogued as COSV55884988; called by muse, mutect2, varscan2
- ANKRD13C | chr1:70355176 G>A | 5'Flank (SNP) | VAF 11/29 reads (38%) | catalogued as COSV52032252; called by muse, mutect2, varscan2
- LMO3 | c.*2C>G | 3'UTR (SNP) | VAF 82/249 reads (33%) | catalogued as COSV53783309; called by muse, mutect2, varscan2
- RPL31P57 | n.148C>T | RNA (SNP) | VAF 12/68 reads (18%) | catalogued as rs367584045; called by muse, mutect2, varscan2
- SSPOP | n.10447C>A | RNA (SNP) | VAF 20/67 reads (30%) | catalogued as rs752498176, COSV100947791, COSV65131423; called by muse, mutect2, varscan2
- ZNF658B | n.2335G>C | RNA (SNP) | VAF 34/136 reads (25%) | called by mutect2, varscan2
